Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KW, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KW-01A (Primary Tumor).

[page 1 of 2]
ICD-3
Carcinoma, Adrenal Cortical 8370/3

Site: ④ Adrenal Gland Cortex C74.0
9/2/013

Procedure: R adrenal resection

Gross description: 108g, 8.5 x 6 x 5.7cm, tumor 7.1 x 5 x 4.8cm

Diagnosis: adrenocortical carcinoma, KI67 1-2%, pT2 pN1 (8/9) L1 V1 Pn0 R0

Reference Pathology: none

4/12/13

Additional path shows LN involvement.

MALIGNANT. BCR

Process - get more path if con passes.
May not stay if not malignant.

NIPTAA Discrepancy		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Right

Tumor size(s)
7.1x5x4.8cm

Histologic diagnosis
ACC

Lymph Node Status
8/9

Pathologic information
T2N1Mx

Weiss score

Source: NCI Genomic Data Commons file a949828e-b4b9-4e1c-b7ad-719cb3717562 (TCGA-OR-A5KW.751F5B53-9186-4602-B824-8593E63EAC3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).